Somatic mutation profile of tumor specimen ALCH-B55L-TTP1-A (aliquot ALCH-B55L-TTP1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-B55L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.8 years (22,224 days).
Specimen ALCH-B55L-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4d78ba9-0a6e-4768-9458-58958ca9e030.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B55L-NB1-A (Blood Derived Normal), aliquot ALCH-B55L-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42d87f62-6064-4773-90ab-d0b4a8ce6af4

The open-access MAF lists 37 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Intron 3, 5'UTR 2, 3'Flank 2, Splice Region 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 80/474 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 90/641 reads (14%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 70/381 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780071, CM120848, COSV52677226, COSV52796536, COSV53623808; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CACNA1B | c.6928G>A p.V2310M | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.224); catalogued as rs201689533, COSV53130333; called by muse, mutect2, varscan2
- CBY2 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.035); catalogued as rs1453986677, COSV60117059; called by muse, mutect2, varscan2
- ITPRIPL2 | c.277C>G p.R93G | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs895223555, COSV67347862; called by muse, mutect2
- OR51E2 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 74/368 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs151286283; called by muse, mutect2, varscan2
- OR52I1 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 62/336 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV56168948; called by muse, mutect2, varscan2
- PADI1 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs199865290, COSV64937949; called by muse, mutect2
- PALB2 | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 30/1060 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55166005; called by muse, mutect2
- PPP2R3A | c.1579C>G p.L527V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.591); catalogued as rs767694067; called by muse, mutect2, varscan2
- SERPINE2 | c.1076-4G>A | Splice Region (SNP) | VAF 56/320 reads (18%) | catalogued as rs567218200; called by muse, mutect2, varscan2
- TMEM71 | c.762G>A p.M254I (on ENST00000523829 / NM_001382398.1; = p.M235I on NM_144649.3) | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs372197272; called by muse, mutect2, varscan2
- ANKRD11 | c.6532G>A p.D2178N | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AQP8 | c.21G>A p.M7I | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CRACDL | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- DMXL2 | c.5245C>T p.Q1749* | Nonsense Mutation (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- FAM178B | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 49/369 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- MBD1 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOP14 | c.116A>G p.Q39R | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- NT5DC3 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PCK1 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- ALDH9A1 | c.483A>T p.G161= | Silent (SNP) | VAF 56/296 reads (19%) | called by muse, mutect2, varscan2
- C2CD4C | c.694C>T p.L232= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- ERLIN2 | c.351C>T p.F117= | Silent (SNP) | VAF 63/617 reads (10%) | called by muse, mutect2, varscan2
- GABPB2 | c.585A>T p.A195= | Silent (SNP) | VAF 62/385 reads (16%) | called by muse, mutect2, varscan2
- GABRB3 | c.1065G>A p.K355= | Silent (SNP) | VAF 54/608 reads (9%) | catalogued as COSV100157963, COSV54674152; called by muse, mutect2
- KPRP | c.1173T>C p.C391= | Silent (SNP) | VAF 36/265 reads (14%) | catalogued as rs777548212, COSV64222811; called by muse, mutect2, varscan2
- KRT20 | c.591G>T p.L197= | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- WASF3 | c.1245G>A p.S415= | Silent (SNP) | VAF 30/180 reads (17%) | catalogued as rs148684191; called by muse, mutect2, varscan2
- AC136604.1 | chr5:179652317 G>A | 3'Flank (SNP) | VAF 113/623 reads (18%) | catalogued as rs199867011; called by muse, mutect2, varscan2
- ADGRB2 | c.3353+125G>T | Intron (SNP) | VAF 14/334 reads (4%) | called by muse, mutect2
- BEAN1 | chr16:66485084 G>A | 3'Flank (SNP) | VAF 44/260 reads (17%) | catalogued as rs1413050997; called by muse, varscan2
- NDRG2 | c.407+12G>T | Intron (SNP) | VAF 7/154 reads (5%) | called by muse, mutect2
- RBPJ | c.-87G>A | 5'UTR (SNP) | VAF 33/201 reads (16%) | called by muse, mutect2, varscan2
- RNF111 | c.2867+850C>T | Intron (SNP) | VAF 37/257 reads (14%) | catalogued as rs1412228927; called by muse, mutect2, varscan2
- RNF6 | c.-3del | 5'UTR (DEL) | VAF 22/121 reads (18%) | called by mutect2, pindel, varscan2
